HCMI case HCM-BROD-0476-C56 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/30eb4b39-20c9-4d1c-8d87-ec84971943fc

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1966; Vital status: Alive.

Diagnoses (2)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Classification of tumor: primary; Age at diagnosis: 43.8 years (16,008 days); Prior malignancy: no.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 1,990 days (5.4 years); Days to treatment end: 2,149 days (5.9 years).
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Pegylated Liposomal Doxorubicin Hydrochloride; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 2,265 days (6.2 years); Days to treatment end: 2,265 days (6.2 years).
   Recorded as not given: adjuvant Hormone Therapy, for residual disease; adjuvant Immunotherapy (Including Vaccines), for residual disease; adjuvant Radiation Therapy, NOS, for residual disease; adjuvant Targeted Molecular Therapy, for residual disease.
2. Serous cystadenocarcinoma, NOS: ICD-O-3 morphology code: 8441/6; ICD-10 code: C79.6; Tissue or organ of origin: Ovary; Site of resection or biopsy: Peritoneum, NOS; Classification of tumor: metastasis; Age at diagnosis: 51.9 years (18,966 days); Days to diagnosis: 2,958 days (8.1 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Anastrozole + Carboplatin + Encorafenib + Paclitaxel + Pegylated Liposomal Doxorubicin Hydrochloride; Treatment intent type: Maintenance Therapy; Days to treatment start: 1,990 days (5.4 years); Days to treatment end: 3,102 days (8.5 years).

Follow-up (1 entry)
- Days to follow up: 3,172 days (8.7 years); Disease response: Progressive Disease; Progression or recurrence: Yes.

Molecular and laboratory tests
- BRCA1 mutation, nos (WXS): Negative.
- BRCA2 mutation, nos (WXS): Negative.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 54 kg; Height: 162 cm; BMI: 20.6.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample HCM-BROD-0476-C56-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
- Sample HCM-BROD-0476-C56-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 13.
